Gene-level copy-number profile of tumor specimen TCGA-DX-AB2T-01A from TCGA case TCGA-DX-AB2T, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 54.1 years (19,749 days).
Specimen TCGA-DX-AB2T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.72d656d5-5de3-4979-80b4-7e10e6f52abe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e492b184-22d7-4a79-9eae-6c18a24e5a91

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,375; copy number 2: 10,806; copy number 3: 14,833; copy number 4: 24,078; copy number 5: 4,789; copy number 6: 2,813; copy number 7: 673; copy number 8: 207; copy number 9: 224; copy number 10: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2T-01A-11D-A386-01): tumor purity 0.65, ploidy 3.52, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 237 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:121,530,422–122,887,691, 13 genes, copy number 10 (within-gene range 7–10): AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1.
- chr2:129,496,297–138,501,698, 216 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr2:138,669,157–138,975,006, 5 genes, copy number 9: NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1.
- chr17:71,011,997–71,298,218, 3 genes, copy number 9: AC005181.1, CASC17, RNU7-155P.

Autosomal genes at a single copy (total copy number 1): 1,375. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
